Somatic mutation profile of tumor specimen TCGA-BS-A0UM-01A (aliquot TCGA-BS-A0UM-01A-11W-A10C-09) from TCGA case TCGA-BS-A0UM, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G1; Age at diagnosis: 64.1 years (23,400 days).
Specimen TCGA-BS-A0UM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ad98c498-e772-402d-b28f-6e1adbf499ef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BS-A0UM-10A (Blood Derived Normal), aliquot TCGA-BS-A0UM-10A-01D-A10B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a64f1650-2d4d-4084-bc03-a4cc012e233e

The open-access MAF lists 563 somatic variants for this specimen: 433 protein-altering or splice-affecting, 124 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 281, Silent 124, Frame Shift Del 84, Nonsense Mutation 22, Frame Shift Ins 19, Splice Site 12, In Frame Del 9, Splice Region 5, Intron 4, Translation Start Site 1, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASPA | c.244dup p.M82Nfs*8 | Frame Shift Ins (INS) | VAF 20/92 reads (22%) | catalogued as rs756198538; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ASPM | c.5149del p.I1717* | Frame Shift Del (DEL) | VAF 27/121 reads (22%) | catalogued as rs199422167, CD077387; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3CA | c.3139C>T p.H1047Y | Missense Mutation (SNP) | VAF 15/93 reads (16%) | hotspot (GDC flag); SIFT tolerated (1); PolyPhen benign (0); catalogued as rs121913281, CM126699, COSV55876499, COSV55912376; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.632dup p.C211Wfs*32 | Frame Shift Ins (INS) | VAF 37/164 reads (23%) | catalogued as rs1114167663, CI004544; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PTEN | c.938del p.K313Rfs*4 | Frame Shift Del (DEL) | VAF 48/226 reads (21%) | catalogued as rs1554825571; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TNNT2 | c.311G>A p.R104H | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs397516457, CM0910206, CM994074, COSV52663672; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.4315C>A p.L1439I (on ENST00000272895 / NM_173076.3; = p.L1121I on NM_015657.3) | Missense Mutation (SNP) | VAF 24/249 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55976492; called by muse, mutect2, varscan2
- ABCB6 | c.567G>A p.W189* | Nonsense Mutation (SNP) | VAF 5/24 reads (21%) | catalogued as COSV54701106; called by muse, mutect2, varscan2
- ABCC1 | c.479C>T p.A160V | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.579); catalogued as rs746254153, COSV60694479; called by muse, mutect2, varscan2
- ADGRD1 | c.2441G>C p.R814T | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV55458148; called by muse, mutect2, varscan2
- ADGRE2 | c.2352+2T>C p.X784_splice | Splice Site (SNP) | VAF 8/117 reads (7%) | catalogued as COSV59696509; called by muse, mutect2
- ADHFE1 | c.344C>T p.T115M | Missense Mutation (SNP) | VAF 47/217 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs767967392, COSV52559347; called by muse, mutect2, varscan2
- ADSS2 | c.734C>A p.P245Q | Missense Mutation (SNP) | VAF 38/383 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.1); catalogued as COSV63696344; called by muse, mutect2, varscan2
- AKAP8L | c.1453G>A p.A485T | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.944); catalogued as rs1458753748, COSV68474725; called by muse, mutect2
- AKR7L | c.835G>A p.A279T | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as rs1430202501, COSV70167939; called by muse, mutect2
- AL163636.1 | c.19G>A p.V7I | Missense Mutation (SNP) | VAF 28/152 reads (18%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.024); catalogued as rs1566602182, COSV59012001; called by muse, mutect2, varscan2
- ALOX12 | c.1114G>A p.A372T | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.119); catalogued as COSV52352377; called by muse, mutect2, varscan2
- ALPK3 | c.3839T>A p.I1280N | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51940216; called by mutect2, varscan2
- ALS2 | c.4580G>T p.R1527M | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.149); catalogued as COSV51892837; called by muse, mutect2
- ANGEL2 | c.949C>T p.R317* | Nonsense Mutation (SNP) | VAF 16/134 reads (12%) | catalogued as rs752882028, COSV64737111; called by muse, mutect2, varscan2
- ANKRD7 | c.185C>A p.P62H | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54555498, COSV54556590; called by muse, mutect2
- AP1M2 | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs779825381, COSV51569626; called by muse, mutect2, varscan2
- API5 | c.793C>T p.Q265* | Nonsense Mutation (SNP) | VAF 18/109 reads (17%) | catalogued as COSV66635225; called by muse, mutect2, varscan2
- APMAP | c.945del p.Y316Tfs*29 | Frame Shift Del (DEL) | VAF 4/33 reads (12%) | catalogued as rs777444320; called by mutect2, pindel, varscan2
- ARFGAP2 | c.276del p.R93Afs*43 | Frame Shift Del (DEL) | VAF 11/31 reads (35%) | catalogued as rs772728725, COSV54066450; called by mutect2, pindel, varscan2
- ARHGAP31 | c.830T>A p.V277D | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV51799513; called by muse, mutect2, varscan2
- ARHGAP5 | c.4330C>A p.Q1444K (on ENST00000345122 / NM_001030055.2; = p.Q1443K on NM_001173.3) | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV53735613; called by muse, mutect2, varscan2
- ARHGEF1 | c.934C>T p.R312W | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs782161306, COSV61526295; called by muse, mutect2
- ARHGEF2 | c.1082G>A p.R361H (on ENST00000361247 / NM_001162383.2; = p.R333H on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV58114766; called by muse, mutect2, varscan2
- ARID1A | c.3219G>A p.W1073* | Nonsense Mutation (SNP) | VAF 9/62 reads (15%) | catalogued as COSV61375653; called by muse, mutect2, varscan2
- ARID1B | c.3484C>T p.Q1162* | Nonsense Mutation (SNP) | VAF 4/14 reads (29%) | catalogued as rs1554231898; called by mutect2, varscan2
- ARID4B | c.2947G>T p.E983* | Nonsense Mutation (SNP) | VAF 23/126 reads (18%) | catalogued as COSV51610100, COSV51611617; called by muse, mutect2, varscan2
- ASAP2 | c.2336C>A p.P779H | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.635); catalogued as COSV55639134; called by muse, mutect2, varscan2
- ATAD2 | c.1178G>A p.R393Q | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.105); catalogued as rs754909018, COSV54887015; called by muse, mutect2, varscan2
- ATF7IP | c.482C>G p.S161C | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.006); catalogued as rs202238899, COSV53778354; called by muse, mutect2, varscan2
- ATM | c.2320G>T p.G774C | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV53776543; called by muse, mutect2, varscan2
- ATP1B1 | c.221C>T p.P74L | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs1002822395, COSV63179198; called by muse, mutect2
- ATP4A | c.1397C>T p.A466V | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV52871949; called by muse, mutect2, varscan2
- ATP6V0C | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as COSV53550087; called by muse, mutect2, varscan2
- ATP7B | c.1545T>C p.G515= | Splice Region (SNP) | VAF 10/38 reads (26%) | catalogued as CD164075, COSV54444605; called by muse, mutect2, varscan2
- BAZ2A | c.1706G>A p.G569D | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.977); catalogued as COSV51644131; called by muse, mutect2, varscan2
- BEND5 | c.1052del p.K351Rfs*15 | Frame Shift Del (DEL) | VAF 68/293 reads (23%) | catalogued as rs756345162, COSV65718189; called by mutect2, varscan2
- BOC | c.1918C>T p.R640C | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767756953, COSV56352222; called by muse, mutect2
- BTNL8 | c.410T>C p.V137A | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV51462076; called by muse, mutect2
- C1orf53 | c.269G>A p.G90D | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV66323374; called by muse, mutect2, varscan2
- C1orf56 | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.086); catalogued as COSV54849122; called by muse, mutect2
- C7orf57 | c.842G>A p.S281N | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.969); catalogued as COSV62363903; called by muse, mutect2
- CACNA1C | c.3679G>A p.V1227I | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs373124557; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1E | c.2003G>A p.R668H | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV62384498; called by muse, mutect2, varscan2
- CASP5 | c.533del p.N178Ifs*8 | Frame Shift Del (DEL) | VAF 15/135 reads (11%) | catalogued as rs765105588; called by mutect2, varscan2
- CCDC110 | c.2311T>A p.Y771N | Missense Mutation (SNP) | VAF 22/160 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.943); catalogued as COSV56873471; called by muse, mutect2, varscan2
- CCDC136 | c.2746del p.Q916Rfs*33 | Frame Shift Del (DEL) | VAF 12/53 reads (23%) | catalogued as rs1562972762; called by mutect2, pindel, varscan2
- CCDC173 | c.191G>T p.R64M | Missense Mutation (SNP) | VAF 42/222 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV69573758; called by muse, mutect2, varscan2
- CCDC178 | c.253A>G p.S85G | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55798742; called by muse, mutect2, varscan2
- CCDC61 | c.62G>A p.R21Q | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as rs369246676; called by muse, mutect2, varscan2
- CCNC | c.224G>T p.R75M | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as COSV58334993; called by muse, mutect2, varscan2
- CDC20 | c.491C>A p.T164N | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV60523127; called by muse, mutect2, varscan2
- CDH6 | c.1926del p.E643Sfs*3 | Frame Shift Del (DEL) | VAF 16/91 reads (18%) | catalogued as rs1561075636; called by mutect2, varscan2
- CDK14 | c.1274G>A p.R425Q (on ENST00000380050 / NM_001287135.2; = p.R407Q on NM_012395.3) | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (1); PolyPhen probably damaging (0.921); catalogued as rs546258215, COSV56053031; called by muse, mutect2, varscan2
- CDK8 | c.1066C>T p.R356* | Nonsense Mutation (SNP) | VAF 38/360 reads (11%) | catalogued as COSV67423243; called by muse, mutect2, varscan2
- CDKL1 | c.22del p.I8Lfs*38 | Frame Shift Del (DEL) | VAF 9/55 reads (16%) | catalogued as rs1566616984; called by mutect2, pindel, varscan2
- CDS1 | c.643G>A p.A215T | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.951); catalogued as rs113432734, COSV55689356; called by muse, mutect2, varscan2
- CELA2A | c.639C>T p.N213= | Splice Region (SNP) | VAF 7/34 reads (21%) | catalogued as rs72474554, COSV62748090; called by muse, mutect2, varscan2
- CENPF | c.3268G>T p.A1090S | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.379); catalogued as COSV65279335; called by muse, mutect2
- CHD3 | c.4531C>T p.R1511C | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as rs574676236, COSV57874569; called by muse, mutect2, varscan2
- CHD7 | c.6410C>T p.A2137V | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as CM133781, COSV71114807; called by muse, mutect2
- CLPB | c.1250G>A p.R417Q | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.673); catalogued as rs1244789178, COSV53633907; called by muse, mutect2
- CNOT1 | c.1772G>A p.R591H | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57764018; called by muse, mutect2, varscan2
- CNOT10 | c.537T>G p.I179M | Missense Mutation (SNP) | VAF 26/211 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as COSV59395481; called by muse, mutect2, varscan2
- CNTNAP1 | c.1429C>T p.R477W | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.953); catalogued as rs141390466; called by muse, mutect2, varscan2
- COL27A1 | c.1909G>A p.G637S | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV61930984; called by muse, mutect2, varscan2
- COL5A3 | c.3286G>A p.A1096T | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0.373); catalogued as rs763284986, COSV53406949; called by muse, mutect2, varscan2
- COQ4 | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757173567, COSV55958102; ClinVar: uncertain significance; called by mutect2, varscan2
- CPT2 | c.1247A>T p.N416I | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.102); catalogued as COSV53760485; called by muse, mutect2, varscan2
- CTCF | c.1768G>T p.E590* | Nonsense Mutation (SNP) | VAF 40/246 reads (16%) | catalogued as COSV50525552, COSV99864080; called by muse, mutect2, varscan2
- CXCL5 | c.324C>T p.D108= | Splice Region (SNP) | VAF 14/106 reads (13%) | catalogued as rs573521158, COSV56018381; called by muse, mutect2, varscan2
- DCBLD2 | c.1521A>C p.Q507H | Missense Mutation (SNP) | VAF 39/259 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.365); catalogued as COSV58793405; called by muse, mutect2, varscan2
- DCSTAMP | c.853C>T p.P285S | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.316); catalogued as COSV52580253; called by muse, mutect2, varscan2
- DCTN2 | c.599del p.P200Qfs*32 (on ENST00000548249 / NM_001261413.2; = p.P205Qfs*32 on NM_006400.4) | Frame Shift Del (DEL) | VAF 37/155 reads (24%) | catalogued as rs745744034; called by mutect2, pindel, varscan2
- DDX60L | c.3338dup p.L1113Ffs*3 | Frame Shift Ins (INS) | VAF 19/104 reads (18%) | catalogued as rs757771764; called by mutect2, varscan2
- DMXL2 | c.4721G>A p.R1574H | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774865945, COSV51856829; called by muse, mutect2, varscan2
- DNAH6 | c.1561G>C p.V521L | Missense Mutation (SNP) | VAF 18/221 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.027); catalogued as rs978806657, COSV52884823; called by muse, mutect2
- DNAH8 | c.1517del p.P506Lfs*9 | Frame Shift Del (DEL) | VAF 18/142 reads (13%) | catalogued as rs747799823; called by mutect2, pindel, varscan2
- DNAJC15 | c.369T>G p.N123K | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV64873238; called by muse, mutect2, varscan2
- DNAJC27 | c.241-1G>T p.X81_splice | Splice Site (SNP) | VAF 8/81 reads (10%) | catalogued as COSV53094766, COSV53096931; called by muse, mutect2
- DOCK2 | c.3659A>G p.Y1220C | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs1183186367, COSV56944674; called by muse, mutect2, varscan2
- DOCK3 | c.700G>A p.D234N | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as rs201614726, COSV56547861; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 4/21 reads (19%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOP1A | c.931A>G p.N311D | Missense Mutation (SNP) | VAF 11/133 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV52718578; called by muse, mutect2
- DPEP3 | c.425C>T p.A142V | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.04); catalogued as COSV52052967; called by muse, mutect2
- DTNBP1 | c.428A>C p.E143A | Missense Mutation (SNP) | VAF 9/149 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as COSV59044208; called by muse, mutect2
- EFL1 | c.1491G>T p.Q497H | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV51610195; called by muse, mutect2, varscan2
- ELF4 | c.799C>T p.R267W | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs984573393, COSV57455269; called by muse, mutect2
- EMSY | c.2235G>T p.Q745H | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as COSV58266265; called by muse, mutect2
- EPHA10 | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.958); catalogued as rs370045860; called by muse, mutect2, varscan2
- EPHB2 | c.1702C>T p.R568W (on ENST00000400191 / NM_001309193.2; = p.R569W on NM_004442.7) | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs200219468, CM065141; called by muse, mutect2, varscan2
- EPS8L3 | c.811A>G p.K271E | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.146); catalogued as rs757805508, COSV62608813, COSV62610601; called by muse, mutect2
- ERCC6L | c.1454C>T p.S485L | Missense Mutation (SNP) | VAF 23/197 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs762834270, COSV57822458; called by muse, mutect2, varscan2
- ESRRB | c.346G>A p.G116S | Missense Mutation (SNP) | VAF 2/16 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1393335116, COSV55062083, COSV55065672; called by muse, mutect2
- EXOC1 | c.1938C>A p.N646K | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.811); catalogued as COSV62122114; called by muse, mutect2, varscan2
- FAM104B | c.160A>G p.N54D | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as COSV59779620; called by muse, mutect2
- FAM120C | c.2839+1G>A p.X947_splice | Splice Site (SNP) | VAF 6/56 reads (11%) | catalogued as COSV60262683; called by muse, mutect2
- FAM120C | c.2510C>A p.A837D | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60262687; called by muse, mutect2
- FAM135B | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.153); catalogued as rs538422547, COSV50523174; called by muse, mutect2, varscan2
- FAM78B | c.406G>A p.V136I | Missense Mutation (SNP) | VAF 11/165 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.075); catalogued as rs368578294; called by muse, mutect2
- FAP | c.1324C>A p.H442N | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs546543927, COSV51867892; called by muse, mutect2, varscan2
- FAT2 | c.1310C>T p.P437L | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs374620930; called by muse, mutect2
- FLG | c.11594A>G p.Q3865R | Missense Mutation (SNP) | VAF 13/148 reads (9%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.873); catalogued as rs1385434818, COSV64249996; called by muse, mutect2
- GAS8 | c.938G>A p.R313H | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.131); catalogued as rs537083866, COSV51946366; called by muse, mutect2, varscan2
- GDI1 | c.677A>T p.Y226F | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50133250; called by muse, mutect2, varscan2
- GHR | c.1640C>T p.A547V | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.284); catalogued as rs886060642, COSV50132434; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GKAP1 | c.967A>G p.T323A | Missense Mutation (SNP) | VAF 20/169 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as COSV64487328; called by muse, mutect2, varscan2
- GLS | c.1195_1197del p.K399del | In Frame Del (DEL) | VAF 8/59 reads (14%) | catalogued as rs1179698897; called by pindel, varscan2
- GNG12 | c.202dup p.T68Nfs*9 | Frame Shift Ins (INS) | VAF 24/125 reads (19%) | catalogued as rs1022402829; called by mutect2, varscan2
- GNG4 | c.148C>T p.R50W | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs747916965, COSV100782656, COSV63998919; called by muse, mutect2, varscan2
- GNL3L | c.560T>A p.L187Q | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV60577721; called by muse, mutect2, varscan2
- GNRHR | c.431C>T p.T144M | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs781358925, COSV56935006; called by muse, mutect2, varscan2
- GRIA3 | c.2647G>T p.G883C | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV52081329; called by muse, mutect2
- GRID2 | c.528C>T p.Y176= | Splice Region (SNP) | VAF 9/39 reads (23%) | catalogued as rs772186189, COSV56270252; called by muse, mutect2, varscan2
- HAX1 | c.5G>A p.S2N | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV55181683; called by muse, mutect2
- HCFC2 | c.780del p.F260Lfs*30 | Frame Shift Del (DEL) | VAF 18/92 reads (20%) | catalogued as COSV57558613; called by mutect2, pindel, varscan2
- HDAC5 | c.604G>A p.G202S | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.046); catalogued as rs778483531, COSV56822132; called by mutect2, varscan2
- HERC1 | c.7520A>G p.Q2507R | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.69); PolyPhen probably damaging (0.932); catalogued as COSV71250394; called by muse, mutect2, varscan2
- HERC2 | c.12821G>A p.G4274D | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55351355; called by muse, mutect2
- HERC4 | c.2261G>A p.R754H (on ENST00000395198 / NM_022079.3; = p.R746H on NM_015601.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as rs753652704, COSV53270657; called by muse, mutect2, varscan2
- HINT1 | c.112-1G>A p.X38_splice | Splice Site (SNP) | VAF 35/235 reads (15%) | catalogued as COSV58343693; called by muse, mutect2, varscan2
- HIVEP1 | c.93del p.E32Kfs*17 | Frame Shift Del (DEL) | VAF 38/214 reads (18%) | catalogued as rs1561928340; called by mutect2, pindel, varscan2
- HMCN1 | c.955T>C p.F319L | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV54943630; called by muse, mutect2
- HMGCS2 | c.41T>C p.L14P | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.193); catalogued as COSV65569390; called by muse, mutect2, varscan2
- HOXD12 | c.760C>T p.R254C | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101184319; called by muse, mutect2
- HTT | c.5573C>T p.P1858L | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs377136202; called by muse, mutect2
- ICA1 | c.611del p.N204Tfs*5 | Frame Shift Del (DEL) | VAF 25/156 reads (16%) | catalogued as rs747841314; called by mutect2, varscan2
- IFNG | c.58G>A p.G20S | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT tolerated (0.85); PolyPhen benign (0.03); catalogued as COSV57492102; called by muse, mutect2
- IFT122 | c.749G>A p.R250H (on ENST00000348417 / NM_052989.3; = p.R191H on NM_018262.4) | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs143145156; called by muse, mutect2, varscan2
- IL27RA | c.1665G>A p.W555* | Nonsense Mutation (SNP) | VAF 5/24 reads (21%) | catalogued as COSV54603364; called by muse, mutect2, varscan2
- IMPDH2 | c.1523+1G>A p.X508_splice | Splice Site (SNP) | VAF 5/28 reads (18%) | catalogued as rs748863433, COSV58247612; called by muse, mutect2, varscan2
- INPP4A | c.2486G>A p.R829Q (on ENST00000074304 / NM_001134224.1; = p.R790Q on NM_001566.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/173 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as rs775014766, COSV50790352, COSV50801650; called by muse, mutect2, varscan2
- INPP4B | c.2102C>A p.S701Y | Missense Mutation (SNP) | VAF 39/241 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV53746784; called by muse, mutect2, varscan2
- IPMK | c.965G>T p.R322M | Missense Mutation (SNP) | VAF 8/170 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.516); catalogued as COSV64244696; called by muse, mutect2
- IQCF1 | c.263T>C p.L88P | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769788183, COSV58824155; called by mutect2, varscan2
- ITGAL | c.2536G>A p.E846K | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.189); catalogued as rs146031122, COSV100776226; called by muse, mutect2, varscan2
- ITSN1 | c.173del p.L58* | Frame Shift Del (DEL) | VAF 63/292 reads (22%) | catalogued as rs1311201242; called by mutect2, pindel, varscan2
- IZUMO1R | c.439C>T p.R147C (on ENST00000440961; = p.R154C on NM_001199206.3) | Missense Mutation (SNP) | VAF 24/158 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as rs761518681, COSV60623641; called by muse, mutect2, varscan2
- JAGN1 | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs1162482675, COSV57062995; called by muse, mutect2
- JAK1 | c.3100T>A p.Y1034N | Missense Mutation (SNP) | VAF 4/57 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53811102, COSV99605795; called by muse, mutect2
- JAM3 | c.745dup p.V249Gfs*28 | Frame Shift Ins (INS) | VAF 10/60 reads (17%) | catalogued as rs763250381; called by mutect2, varscan2
- KANK1 | c.1633_1636del p.N545Vfs*2 | Frame Shift Del (DEL) | VAF 16/60 reads (27%) | catalogued as rs1193918189; called by pindel, varscan2
- KAT6A | c.2063G>A p.R688H | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs368565180; called by muse, mutect2
- KAT6B | c.3139C>T p.H1047Y | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0.139); catalogued as COSV54755182; called by muse, mutect2, varscan2
- KCNB2 | c.435del p.E146Nfs*3 | Frame Shift Del (DEL) | VAF 16/94 reads (17%) | catalogued as rs752059864; called by mutect2, varscan2
- KDM3B | c.3073C>T p.R1025C | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs763983126, COSV58687503; called by muse, mutect2, varscan2
- KDM3B | c.3848C>T p.A1283V | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.018); catalogued as COSV58695643; called by muse, mutect2, varscan2
- KIAA1549 | c.2053C>G p.L685V | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54329291; called by muse, mutect2, varscan2
- KIAA2026 | c.4616A>T p.Y1539F | Missense Mutation (SNP) | VAF 37/223 reads (17%) | SIFT tolerated (0.63); PolyPhen benign (0.006); catalogued as COSV67357882; called by muse, mutect2, varscan2
- KLK15 | c.728G>A p.C243Y | Missense Mutation (SNP) | VAF 39/196 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV56828702; called by muse, mutect2, varscan2
- KMT2B | c.7699C>T p.R2567C | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.072); catalogued as rs1393734909, COSV53074326; called by muse, mutect2, varscan2
- KMT5B | c.402G>T p.Q134H | Missense Mutation (SNP) | VAF 11/156 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV58565810; called by muse, mutect2
- KPNA3 | c.1000C>T p.L334F | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1566333266, COSV55507448, COSV99904261; called by muse, mutect2
- KRT20 | c.1042C>T p.R348C | Missense Mutation (SNP) | VAF 18/250 reads (7%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.938); catalogued as rs780211829, COSV51424627; called by muse, mutect2
- KRT31 | c.400G>A p.A134T | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.951); catalogued as rs1408804201, COSV52436647; called by muse, mutect2, varscan2
- KRT6C | c.1425-1G>T p.X475_splice | Splice Site (SNP) | VAF 20/88 reads (23%) | catalogued as COSV52880697; called by muse, mutect2
- KRT72 | c.587G>T p.R196M | Missense Mutation (SNP) | VAF 21/188 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53376983; called by muse, mutect2, varscan2
- LAMB2 | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs369040269; called by muse, varscan2
- LARP1B | c.1147C>A p.P383T | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.014); catalogued as COSV52803262; called by muse, mutect2, varscan2
- LARP7 | c.82C>T p.R28W | Missense Mutation (SNP) | VAF 6/144 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1256714961, COSV60521690; called by muse, mutect2
- LIFR | c.208C>A p.P70T | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as COSV54700782; called by muse, mutect2, varscan2
- LRG1 | c.613C>T p.P205S | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.018); catalogued as COSV56706192; called by muse, mutect2, varscan2
- LRP8 | c.1330C>T p.R444C | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as rs773004205, COSV60096851; called by muse, mutect2, varscan2
- LRRC36 | c.754+2T>C p.X252_splice | Splice Site (SNP) | VAF 14/118 reads (12%) | catalogued as COSV52082408; called by muse, mutect2, varscan2
- LRRC36 | c.2233G>A p.V745I | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.001); catalogued as rs151167803; called by muse, mutect2
- LRRC7 | c.1813C>T p.R605* (on ENST00000651989 / NM_001370785.2; = p.R572* on NM_001330635.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 21/96 reads (22%) | catalogued as COSV50485026; called by muse, mutect2, varscan2
- LRRIQ1 | c.1537G>A p.G513R | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as COSV67839143; called by muse, mutect2
- MAGEB18 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as COSV57465120; called by muse, mutect2, varscan2
- MAGIX | c.530T>C p.I177T | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV66256667; called by muse, mutect2
- MAML1 | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.647); catalogued as rs1485874595, COSV52984567; called by muse, mutect2, varscan2
- MAP3K1 | c.2784_2785insTA p.E929* | Frame Shift Ins (INS) | VAF 15/66 reads (23%) | catalogued as COSV68127623; called by mutect2, pindel, varscan2
- MAP3K20 | c.1769G>A p.R590H | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0); catalogued as rs200257993; called by muse, mutect2, varscan2
- MAP4K4 | c.754C>T p.R252W | Missense Mutation (SNP) | VAF 19/195 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV56340985; called by muse, mutect2
- MAPK1IP1L | c.35C>G p.P12R | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV67106849; called by muse, mutect2, varscan2
- MAPK9 | c.667G>A p.V223M | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV58126368; called by muse, mutect2, varscan2
- MARK4 | c.851A>T p.E284V | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53469101; called by muse, mutect2, varscan2
- MBTD1 | c.1361C>A p.T454N | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV64504420; called by muse, mutect2
- MED13 | c.5272C>T p.R1758* | Nonsense Mutation (SNP) | VAF 14/108 reads (13%) | catalogued as COSV67263544; called by muse, mutect2, varscan2
- MEGF11 | c.337G>A p.V113I | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.875); catalogued as rs753304245, COSV56545786; called by muse, mutect2, varscan2
- MIA2 | c.2023G>A p.V675M | Missense Mutation (SNP) | VAF 42/360 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.119); catalogued as rs999158777, COSV54491792; called by muse, mutect2, varscan2
- MORC1 | c.2420C>T p.A807V | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs777848808, COSV51719083, COSV51731709; called by muse, mutect2, varscan2
- MPZL1 | c.358A>C p.I120L | Missense Mutation (SNP) | VAF 28/364 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63257402; called by muse, mutect2
- MRPL9 | c.356G>A p.G119D | Missense Mutation (SNP) | VAF 31/220 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.889); catalogued as rs1446165875, COSV58619723; called by muse, mutect2, varscan2
- MTREX | c.56C>T p.T19I | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs372799056; called by muse, mutect2, varscan2
- MYG1 | c.395C>T p.A132V | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs142439022; called by mutect2, varscan2
- MYH11 | c.2026G>A p.V676M | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs926424189, COSV55558920; called by mutect2, varscan2
- MYH4 | c.2156A>G p.Y719C | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV55126810; called by muse, mutect2, varscan2
- MYH8 | c.4225G>T p.A1409S | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.204); catalogued as COSV67960498, COSV67972922; called by muse, mutect2, varscan2
- MYRF | c.2723A>G p.H908R (on ENST00000278836 / NM_001127392.3; = p.H873R on NM_013279.4) | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as COSV53894345; called by muse, mutect2, varscan2
- NAV1 | c.5324C>T p.A1775V | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.174); catalogued as COSV55226969; called by muse, mutect2, varscan2
- NCAN | c.3873C>G p.H1291Q | Missense Mutation (SNP) | VAF 37/282 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.386); catalogued as rs1391071833, COSV53059541; called by muse, mutect2, varscan2
- NCKAP1L | c.1663A>G p.T555A | Missense Mutation (SNP) | VAF 39/235 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.147); catalogued as COSV53212670; called by muse, mutect2, varscan2
- NCOR2 | c.1586C>T p.A529V | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs376669119, COSV62304820; called by muse, mutect2, varscan2
- NDRG3 | c.983G>A p.R328Q (on ENST00000349004 / NM_032013.4; = p.R316Q on NM_022477.4) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as rs1182325536, COSV62423666; called by muse, mutect2, varscan2
- NDST3 | c.1931G>T p.R644M | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV56630237; called by muse, mutect2, varscan2
- NDUFA10 | c.604dup p.H202Pfs*25 | Frame Shift Ins (INS) | VAF 12/62 reads (19%) | catalogued as rs746019378; ClinVar: uncertain significance; called by mutect2, varscan2
- NDUFA10 | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs201308887, COSV53156509; called by muse, mutect2, varscan2
- NDUFS1 | c.854G>T p.W285L | Missense Mutation (SNP) | VAF 23/155 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51913937; called by muse, mutect2
- NIN | c.3422G>A p.R1141Q | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs370714110; called by muse, mutect2
- NIPAL3 | c.575A>G p.Y192C | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV50237902; called by muse, mutect2, varscan2
- NKTR | c.1287dup p.R430Tfs*8 | Frame Shift Ins (INS) | VAF 12/72 reads (17%) | catalogued as rs768773004; called by mutect2, pindel, varscan2
- NLGN4X | c.1175C>A p.P392H | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.573); catalogued as COSV52038087; called by muse, mutect2, varscan2
- NPFFR2 | c.1145C>T p.A382V | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.336); catalogued as rs771712220, COSV58154692; called by muse, mutect2, varscan2
- NPHS1 | c.3554del p.P1185Rfs*52 | Frame Shift Del (DEL) | VAF 5/33 reads (15%) | catalogued as COSV100800437, COSV62287222; called by mutect2, pindel, varscan2
- NRXN1 | c.2153T>G p.V718G | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); catalogued as COSV58455038; called by muse, mutect2, varscan2
- NT5E | c.817C>T p.R273W | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs775412849, COSV57630435; called by muse, mutect2, varscan2
- NUDT17 | c.873A>T p.Q291H | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as COSV57908722; called by muse, mutect2
- NUP214 | c.2180C>T p.A727V | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.558); catalogued as rs1389504770, COSV63913294; called by muse, mutect2, varscan2
- NWD1 | c.1933C>T p.R645W | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60352208; called by muse, mutect2, varscan2
- OMG | c.201T>G p.F67L | Missense Mutation (SNP) | VAF 59/332 reads (18%) | SIFT tolerated (0.6); PolyPhen benign (0.08); catalogued as COSV55988711; called by muse, mutect2, varscan2
- OR14A16 | c.119A>G p.N40S | Missense Mutation (SNP) | VAF 35/272 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1460580041, COSV62926728, COSV62927532; called by muse, mutect2, varscan2
- OR2T6 | c.764C>T p.A255V | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV63217086; called by muse, mutect2, varscan2
- OR4D6 | c.716C>T p.T239M | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764578155, COSV55660383, COSV55660812; called by muse, mutect2, varscan2
- OR51E1 | c.466del p.A156Lfs*3 | Frame Shift Del (DEL) | VAF 20/160 reads (13%) | catalogued as rs1564877761; called by mutect2, pindel, varscan2
- OR52B4 | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs200744522, COSV101281569; called by muse, mutect2, varscan2
- OR5AR1 | c.215G>C p.G72A | Missense Mutation (SNP) | VAF 46/181 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.054); catalogued as COSV57252964, COSV57255432; called by muse, mutect2, varscan2
- OR5T2 | c.1077del p.K359Nfs*4 | Frame Shift Del (DEL) | VAF 5/22 reads (23%) | catalogued as rs768492646; called by mutect2, pindel, varscan2
- OSMR | c.340A>T p.I114L | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.123); catalogued as COSV57092319; called by muse, mutect2
- OSMR | c.1849del p.T617Qfs*20 | Frame Shift Del (DEL) | VAF 44/334 reads (13%) | catalogued as rs762315064; called by mutect2, pindel, varscan2
- PALLD | c.255A>T p.K85N | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV54995663; called by muse, mutect2, varscan2
- PAPPA | c.3085G>A p.V1029I | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60292303; called by muse, mutect2, varscan2
- PAPPA2 | c.1577G>A p.R526H | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs763746287, COSV62778477; called by muse, mutect2, varscan2
- PARD3B | c.3038C>T p.A1013V (on ENST00000406610 / NM_001302769.2; = p.A944V on NM_057177.7) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1355297240, COSV62511268; called by muse, mutect2, varscan2
- PAX6 | c.1124del p.P375Hfs*7 | Frame Shift Del (DEL) | VAF 7/36 reads (19%) | catalogued as CM011452; called by mutect2, pindel, varscan2
- PBLD | c.514T>C p.S172P | Missense Mutation (SNP) | VAF 7/136 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV53267406; called by muse, mutect2
- PBX3 | c.1172G>A p.G391D | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.06); catalogued as COSV60736165; called by muse, mutect2, varscan2
- PCDH15 | c.1612G>A p.E538K | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.874); catalogued as rs749305630, COSV57257918; called by muse, mutect2, varscan2
- PCLO | c.3763T>C p.S1255P | Missense Mutation (SNP) | VAF 54/322 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs764843170, COSV61668225; called by muse, mutect2, varscan2
- PCP2 | c.358G>A p.A120T | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.009); catalogued as rs147978153; called by muse, mutect2, varscan2
- PDS5B | c.1829C>T p.P610L | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59734851; called by muse, mutect2, varscan2
- PERP | c.216G>T p.A72= | Splice Region (SNP) | VAF 9/77 reads (12%) | catalogued as rs754247576, COSV101408571, COSV69827806; called by muse, mutect2, varscan2
- PEX1 | c.2503A>G p.R835G | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs769868249, COSV50420668; called by muse, mutect2, varscan2
- PGBD4 | c.1751del p.N584Ifs*21 | Frame Shift Del (DEL) | VAF 10/48 reads (21%) | catalogued as rs770560794; called by mutect2, varscan2
- PHIP | c.3874G>A p.V1292M | Missense Mutation (SNP) | VAF 9/231 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.051); catalogued as COSV51511142; called by muse, mutect2
- PHTF2 | c.1513G>A p.A505T (on ENST00000248550 / NM_001366089.1; = p.A467T on NM_020432.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/195 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as COSV50341650; called by muse, mutect2, varscan2
- PIGA | c.110T>C p.M37T | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61238526; called by muse, mutect2
- PIGX | c.761G>A p.G254D | Missense Mutation (SNP) | VAF 37/280 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs773994171, COSV56361476; called by muse, mutect2, varscan2
- PIK3CA | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 15/27 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.05); catalogued as COSV55935970; called by muse, mutect2, varscan2
- PIKFYVE | c.5642G>A p.R1881H | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745698256, COSV52249556; called by muse, mutect2, varscan2
- PITX2 | c.817del p.Y273Ifs*12 (on ENST00000354925 / NM_001204397.1; = p.Y280Ifs*12 on NM_000325.6) | Frame Shift Del (DEL) | VAF 13/51 reads (25%) | catalogued as CD043907; called by mutect2, pindel, varscan2
- PKHD1 | c.6847A>G p.I2283V | Missense Mutation (SNP) | VAF 28/155 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.026); catalogued as rs1554299441, COSV61895702; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLE | c.1696G>A p.A566T | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.531); catalogued as rs773813430, COSV57691211; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPARGC1A | c.1145G>C p.G382A | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV53533885; called by muse, mutect2, varscan2
- PPAT | c.1051C>T p.R351W | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51706784; called by muse, varscan2
- PPP1R12B | c.2398C>T p.R800W | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs3817222, COSV51785001; called by muse, mutect2, varscan2
- PPP1R15A | c.1401C>A p.D467E | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52340341; called by muse, mutect2
- PPP2R1A | c.82C>T p.R28C | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59043218; called by muse, mutect2, varscan2
- PPP2R5D | c.791G>A p.R264H | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764831855, COSV55151522; called by muse, mutect2, varscan2
- PPP6C | c.431A>C p.K144T | Missense Mutation (SNP) | VAF 41/220 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.068); catalogued as COSV65209234; called by muse, mutect2, varscan2
- PREP | c.535C>T p.R179C (on ENST00000369110; = p.R245C on NM_002726.5) | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs149858250; called by muse, mutect2, varscan2
- PRKD1 | c.2360A>G p.E787G | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.574); catalogued as COSV59587552; called by muse, mutect2, varscan2
- PROM1 | c.1927G>A p.A643T | Missense Mutation (SNP) | VAF 11/136 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs748475864, COSV71700020; called by muse, mutect2
- PRPS2 | c.406G>A p.G136R | Missense Mutation (SNP) | VAF 14/237 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66126679; called by muse, mutect2
- PRTFDC1 | c.443G>T p.R148M | Missense Mutation (SNP) | VAF 49/445 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV60777901; called by muse, mutect2, varscan2
- PSG3 | c.127A>G p.T43A | Missense Mutation (SNP) | VAF 178/576 reads (31%) | SIFT tolerated (0.49); PolyPhen benign (0.155); catalogued as COSV59506951; called by muse, mutect2, varscan2
- PSMC4 | c.773C>T p.A258V | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as COSV50098346; called by muse, mutect2, varscan2
- PTEN | c.93C>G p.N31K | Missense Mutation (SNP) | VAF 98/355 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV64307645, COSV64310568; called by muse, mutect2, varscan2
- PTPN4 | c.2722A>G p.I908V | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as COSV55309608; called by muse, mutect2, varscan2
- RAB24 | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57464200; called by muse, mutect2, varscan2
- RADX | c.1447A>G p.K483E | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as COSV65320185; called by muse, mutect2, varscan2
- RAET1G | c.664C>A p.P222T | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.029); catalogued as rs550871292, COSV66275217; called by muse, varscan2
- RAPGEF1 | c.1948C>A p.P650T | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0.018); catalogued as COSV64702482; called by muse, mutect2
- RASGRF1 | c.1013G>A p.R338H | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769894902, COSV101369755, COSV69183544; called by muse, mutect2, varscan2
- RASSF9 | c.25C>A p.L9I | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV63436182; called by muse, mutect2, varscan2
- RB1 | c.1959del p.V654Cfs*4 | Frame Shift Del (DEL) | VAF 20/91 reads (22%) | catalogued as CM1110478, COSV57298520; called by mutect2, pindel, varscan2
- RBMX | c.583C>T p.R195* | Nonsense Mutation (SNP) | VAF 13/88 reads (15%) | catalogued as COSV57811608; called by muse, mutect2, varscan2
- RECK | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.616); catalogued as COSV65036404; called by muse, mutect2, varscan2
- RECK | c.1326del p.K442Nfs*27 | Frame Shift Del (DEL) | VAF 30/195 reads (15%) | catalogued as rs71508012; called by mutect2, pindel, varscan2
- RFC2 | c.227G>C p.G76A | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV50017021; called by muse, mutect2
- RFPL4B | c.551T>C p.M184T | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as COSV71437821; called by muse, mutect2, varscan2
- RFX5 | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.798); catalogued as rs774928260, COSV51841740; called by muse, mutect2, varscan2
- RNF128 | c.131C>T p.T44I | Missense Mutation (SNP) | VAF 7/235 reads (3%) | SIFT tolerated (0.6); PolyPhen benign (0.034); catalogued as COSV60951085; called by muse, mutect2
- RNF169 | c.1244A>T p.N415I | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV55135865; called by muse, mutect2, varscan2
- RNF25 | c.1135del p.L379Sfs*7 | Frame Shift Del (DEL) | VAF 6/36 reads (17%) | catalogued as COSV55309920; called by mutect2, pindel, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 18/32 reads (56%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- ROBO4 | c.572C>T p.S191F | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); catalogued as COSV60628183; called by muse, mutect2, varscan2
- RPL4 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.893); catalogued as COSV57183355; called by muse, mutect2, varscan2
- RSPH14 | c.1004G>A p.R335Q | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.355); catalogued as rs556605808, COSV53272397; called by muse, mutect2, varscan2
- RTTN | c.935G>A p.R312Q | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs367781423; called by muse, mutect2, varscan2
- RWDD4 | c.204dup p.N69* | Frame Shift Ins (INS) | VAF 51/306 reads (17%) | catalogued as rs1325913157; called by mutect2, varscan2
- SASS6 | c.549G>T p.K183N | Missense Mutation (SNP) | VAF 22/185 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.208); catalogued as COSV54930545; called by muse, mutect2, varscan2
- SEC14L1 | c.758C>T p.P253L | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.429); catalogued as rs759470211, COSV66725546; called by muse, mutect2, varscan2
- SEC23B | c.2242G>A p.D748N | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV52724150; called by muse, mutect2, varscan2
- SEMA4F | c.328C>T p.Q110* | Nonsense Mutation (SNP) | VAF 32/176 reads (18%) | catalogued as rs1224602130, COSV60285423; called by muse, mutect2, varscan2
- SETD5 | c.2852G>T p.G951V | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV56717588; called by muse, mutect2, varscan2
- SHPRH | c.4148A>G p.H1383R (on ENST00000275233 / NM_001042683.3; = p.H1387R on NM_173082.3) | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.23); catalogued as COSV51618409; called by muse, mutect2, varscan2
- SHROOM3 | c.489G>A p.W163* | Nonsense Mutation (SNP) | VAF 5/21 reads (24%) | catalogued as COSV56039840; called by mutect2, varscan2
- SIPA1L2 | c.3523G>A p.A1175T | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV53400478; called by muse, mutect2, varscan2
- SLC1A3 | c.1024C>T p.R342W | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1229578292, COSV54314880, COSV99468288; called by muse, mutect2
- SLC30A4 | c.654G>A p.M218I | Missense Mutation (SNP) | VAF 20/235 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV56007599; called by muse, mutect2
- SLC41A2 | c.1526C>T p.A509V | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV51611367; called by muse, mutect2, varscan2
- SLC46A3 | c.62G>A p.G21D | Missense Mutation (SNP) | VAF 5/122 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs1173861245, COSV57184847; called by muse, mutect2
- SLC6A9 | c.325T>C p.F109L (on ENST00000360584 / NM_201649.4; = p.F55L on NM_006934.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62212216; called by muse, mutect2, varscan2
- SMARCA5 | c.3041A>G p.E1014G | Missense Mutation (SNP) | VAF 24/268 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.851); catalogued as COSV51647465; called by muse, mutect2
- SMPX | c.159G>T p.E53D | Missense Mutation (SNP) | VAF 13/267 reads (5%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as COSV65278384; called by muse, mutect2
- SNRPN | c.670C>T p.P224S | Missense Mutation (SNP) | VAF 7/117 reads (6%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); catalogued as COSV57600732; called by muse, mutect2
- SPART | c.1139G>A p.R380H | Missense Mutation (SNP) | VAF 42/545 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs956021462, COSV62083449; ClinVar: uncertain significance; called by muse, mutect2
- SPATA13 | c.559G>T p.G187C | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57981658; called by muse, mutect2
- SPECC1 | c.1835T>A p.I612N | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.209); catalogued as COSV54966556; called by muse, mutect2
- SPEF2 | c.2051C>T p.A684V | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1163472143, COSV61553934; called by muse, mutect2
- SRPX | c.1222C>T p.R408* | Nonsense Mutation (SNP) | VAF 4/41 reads (10%) | catalogued as COSV59437504; called by muse, mutect2
- ST6GALNAC3 | c.505G>A p.V169I | Missense Mutation (SNP) | VAF 20/167 reads (12%) | PolyPhen benign (0.09); catalogued as rs200291957; called by muse, mutect2, varscan2
- STAM2 | c.251T>C p.V84A | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV55734235; called by muse, mutect2, varscan2
- STK17A | c.1135G>T p.G379* | Nonsense Mutation (SNP) | VAF 30/155 reads (19%) | catalogued as COSV60048764, COSV60048843; called by muse, mutect2, varscan2
- STRN | c.2298T>G p.Y766* | Nonsense Mutation (SNP) | VAF 12/83 reads (14%) | catalogued as COSV55752372; called by muse, mutect2, varscan2
- STXBP1 | c.853G>T p.D285Y | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM144087, COSV64815561; called by muse, mutect2, varscan2
- STXBP4 | c.1582G>A p.V528M | Missense Mutation (SNP) | VAF 38/145 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.092); catalogued as rs769190974, COSV64467535; called by muse, mutect2, varscan2
- SULT1B1 | c.148+1G>T p.X50_splice | Splice Site (SNP) | VAF 17/120 reads (14%) | catalogued as COSV60209560; called by muse, mutect2, varscan2
- SYMPK | c.443G>T p.R148L | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as COSV55616004; called by muse, mutect2, varscan2
- SYN1 | c.1076C>T p.T359M | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs765183335, COSV55984996; called by muse, mutect2, varscan2
- SYN1 | c.985A>G p.T329A | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV55985008; called by muse, mutect2, varscan2
- SYNPO2 | c.1637C>T p.T546M | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs370448025, COSV61117879; called by muse, mutect2, varscan2
- TAF4B | c.2323C>T p.Q775* | Nonsense Mutation (SNP) | VAF 16/154 reads (10%) | catalogued as COSV52310490; called by muse, mutect2
- TBC1D4 | c.3396G>A p.M1132I | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.176); catalogued as COSV66492385; called by muse, mutect2, varscan2
- TCERG1 | c.2870del p.K957Rfs*17 | Frame Shift Del (DEL) | VAF 12/94 reads (13%) | catalogued as rs758822980; called by mutect2, varscan2
- TIMM17B | c.212del p.G71Afs*28 | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | catalogued as rs782500597; called by pindel, varscan2
- TLR8 | c.2298G>A p.M766I (on ENST00000218032 / NM_138636.5; = p.M784I on NM_016610.4) | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV54320861; called by muse, mutect2
- TMEM255A | c.399G>T p.K133N | Missense Mutation (SNP) | VAF 4/67 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.36); catalogued as COSV59031596; called by muse, mutect2
- TOP2A | c.684G>A p.M228I | Missense Mutation (SNP) | VAF 20/184 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.088); catalogued as COSV70733981; called by muse, mutect2, varscan2
- TP63 | c.796C>T p.R266* | Nonsense Mutation (SNP) | VAF 8/80 reads (10%) | catalogued as COSV53198553; called by muse, mutect2, varscan2
- TRABD2A | c.1162G>A p.A388T (on ENST00000409520 / NM_001277053.2; = p.A339T on NM_001080824.3) | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as COSV52884849; called by muse, mutect2, varscan2
- TRAF6 | c.764G>T p.R255M | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61923684; called by muse, mutect2
- TRAM1 | c.128C>T p.T43M | Missense Mutation (SNP) | VAF 15/162 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV51597931; called by muse, mutect2
- TRANK1 | c.7398C>G p.Y2466* | Nonsense Mutation (SNP) | VAF 15/65 reads (23%) | catalogued as COSV57164776; called by muse, mutect2, varscan2
- TRDN | c.1780del p.T594Qfs*35 | Frame Shift Del (DEL) | VAF 17/171 reads (10%) | catalogued as COSV100521660; called by mutect2, pindel, varscan2
- TRMT10C | c.393del p.K131Nfs*3 | Frame Shift Del (DEL) | VAF 10/24 reads (42%) | catalogued as rs760928888; called by mutect2, varscan2
- TRPA1 | c.739del p.V247Cfs*8 | Frame Shift Del (DEL) | VAF 24/208 reads (12%) | catalogued as COSV100084743, COSV51574665; called by pindel, varscan2
- TRPM8 | c.2206G>A p.V736M | Missense Mutation (SNP) | VAF 21/194 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs200217624; called by muse, mutect2, varscan2
- TSHZ3 | c.1637dup p.Y547Lfs*35 | Frame Shift Ins (INS) | VAF 12/54 reads (22%) | catalogued as rs750388867; called by mutect2, varscan2
- TTC3 | c.2334dup p.E779Rfs*18 | Frame Shift Ins (INS) | VAF 45/208 reads (22%) | catalogued as rs756650873; called by mutect2, varscan2
- TTLL13P | c.740G>A p.R247Q | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1422467536, COSV60038720; called by muse, mutect2, varscan2
- TTN | c.51808G>A p.D17270N (on ENST00000591111; = p.D9846N on NM_003319.4) | Missense Mutation (SNP) | VAF 14/87 reads (16%) | PolyPhen probably damaging (0.998); catalogued as COSV60363220; called by muse, mutect2, varscan2
- TTN | c.9337C>T p.R3113C (on ENST00000591111; = p.R3067C on NM_003319.4) | Missense Mutation (SNP) | VAF 14/72 reads (19%) | PolyPhen probably damaging (0.982); catalogued as rs751998418, COSV59960853; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUB | c.967C>T p.R323* (on ENST00000299506 / NM_177972.3; = p.R378* on NM_003320.4) | Nonsense Mutation (SNP) | VAF 13/56 reads (23%) | catalogued as COSV55110168; called by muse, mutect2, varscan2
- TUT7 | c.2842del p.Y948Mfs*16 | Frame Shift Del (DEL) | VAF 11/88 reads (13%) | catalogued as rs751076382; called by mutect2, varscan2
- TXNDC5 | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.572); catalogued as COSV65731058; called by muse, mutect2, varscan2
- UBA5 | c.1004T>C p.I335T | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV53906592; called by muse, mutect2
- UBB | c.570dup p.D191Rfs*20 | Frame Shift Ins (INS) | VAF 9/48 reads (19%) | catalogued as rs750712511; called by mutect2, varscan2
- UHRF1BP1L | c.1022-1G>T p.X341_splice | Splice Site (SNP) | VAF 8/66 reads (12%) | catalogued as rs1334264508, COSV54442837; called by muse, varscan2
- UMOD | c.1045C>A p.L349M | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1157186215, COSV56780099; called by muse, mutect2, varscan2
- UPP2 | c.722A>G p.Y241C | Missense Mutation (SNP) | VAF 26/171 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV50049653; called by muse, mutect2, varscan2
- USP12 | c.901G>A p.D301N | Missense Mutation (SNP) | VAF 18/176 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.081); catalogued as rs769554767, COSV56659950; called by muse, mutect2, varscan2
- VPS13B | c.10726G>A p.A3576T | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as rs528991858, COSV62157793; called by muse, mutect2, varscan2
- VPS13C | c.4429del p.I1477Lfs*24 (on ENST00000644861 / NM_020821.3; = p.I1434Lfs*24 on NM_017684.5) | Frame Shift Del (DEL) | VAF 37/248 reads (15%) | catalogued as rs756149444; called by mutect2, varscan2
- VPS13D | c.8363C>A p.P2788H | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV50689094; called by muse, mutect2, varscan2
- VWA5A | c.1097del p.G366Afs*38 | Frame Shift Del (DEL) | VAF 15/81 reads (19%) | catalogued as rs764769694, COSV100795589; called by mutect2, pindel, varscan2
- WASHC5 | c.580G>T p.G194C | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59200699; called by muse, mutect2, varscan2
- WASL | c.1263del p.V422Wfs*17 | Frame Shift Del (DEL) | VAF 9/39 reads (23%) | catalogued as rs1158703313; called by mutect2, pindel, varscan2
- WBP4 | c.485del p.K162Rfs*4 | Frame Shift Del (DEL) | VAF 21/172 reads (12%) | catalogued as rs1233055164; called by mutect2, pindel, varscan2
- WDFY2 | c.817G>A p.V273M | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.862); catalogued as rs777737227, COSV53293208; called by muse, mutect2, varscan2
- WDR12 | c.627G>T p.W209C | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV53688818; called by muse, mutect2
- WDR36 | c.164C>T p.A55V | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as COSV72411508; called by muse, mutect2, varscan2
- WNK3 | c.4015-2A>G p.X1339_splice | Splice Site (SNP) | VAF 10/93 reads (11%) | catalogued as COSV63616045; called by muse, mutect2
- XRN1 | c.2518G>A p.D840N | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.043); catalogued as rs368411156; called by muse, mutect2, varscan2
- XRN2 | c.314T>C p.V105A | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65871702; called by muse, mutect2, varscan2
- ZFHX3 | c.8923G>T p.E2975* | Nonsense Mutation (SNP) | VAF 23/68 reads (34%) | catalogued as COSV51737224; called by muse, mutect2, varscan2
- ZMYM4 | c.1290del p.K430Nfs*6 | Frame Shift Del (DEL) | VAF 13/80 reads (16%) | catalogued as rs755663477, COSV58913572; called by mutect2, varscan2
- ZMYND12 | c.995G>T p.R332M | Missense Mutation (SNP) | VAF 73/237 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.28); catalogued as COSV65342633; called by muse, mutect2, varscan2
- ZNF226 | c.2240G>A p.R747Q | Missense Mutation (SNP) | VAF 34/194 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.865); catalogued as rs766519729, COSV56197233; called by muse, mutect2, varscan2
- ZNF385D | c.365C>T p.T122I | Missense Mutation (SNP) | VAF 24/266 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs767593181, COSV55776093; called by muse, mutect2
- ZNF584 | c.832dup p.T278Nfs*22 | Frame Shift Ins (INS) | VAF 7/50 reads (14%) | catalogued as rs746396233; called by mutect2, pindel, varscan2
- ZNF658 | c.2585C>T p.T862M | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs1341410790; called by muse, mutect2, varscan2
- ZNF714 | c.1138C>A p.H380N | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.066); catalogued as COSV52515743; called by muse, mutect2, varscan2
- ZNF77 | c.566C>T p.P189L | Missense Mutation (SNP) | VAF 5/128 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV58822693; called by muse, mutect2
- ZNF793 | c.862del p.C288Vfs*113 | Frame Shift Del (DEL) | VAF 14/58 reads (24%) | catalogued as rs761241629, COSV101495729; called by mutect2, varscan2
- ZNF804B | c.1877C>G p.S626C | Missense Mutation (SNP) | VAF 26/166 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as COSV60817118, COSV60856758; called by muse, mutect2
- ZP3 | c.1061-1G>A p.X354_splice (on ENST00000394857 / NM_001110354.2; = p.X303_splice on NM_007155.6) | Splice Site (SNP) | VAF 16/104 reads (15%) | catalogued as COSV60635682; called by muse, mutect2, varscan2
- AASDH | c.342del p.K114Nfs*14 | Frame Shift Del (DEL) | VAF 12/72 reads (17%) | called by mutect2, varscan2
- AGGF1 | c.964del p.I322* | Frame Shift Del (DEL) | VAF 8/61 reads (13%) | called by mutect2, pindel, varscan2
- AGMO | c.125del p.K42Rfs*9 | Frame Shift Del (DEL) | VAF 20/147 reads (14%) | called by mutect2, pindel, varscan2
- ALS2 | c.2409G>C p.K803N | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AP1AR | c.520_521del p.S174Ifs*15 | Frame Shift Del (DEL) | VAF 32/194 reads (16%) | called by pindel, varscan2
- ARAP3 | c.1535del p.P512Qfs*33 | Frame Shift Del (DEL) | VAF 4/33 reads (12%) | called by mutect2, pindel
- ARHGEF26 | c.2104_2106del p.N702del | In Frame Del (DEL) | VAF 28/175 reads (16%) | called by mutect2, pindel, varscan2
- ARHGEF28 | c.1050dup p.S351Ifs*21 | Frame Shift Ins (INS) | VAF 77/242 reads (32%) | called by mutect2, varscan2
- ARID4B | c.2815del p.T939Rfs*2 | Frame Shift Del (DEL) | VAF 16/114 reads (14%) | called by mutect2, varscan2
- AVIL | c.353del p.G118Vfs*6 | Frame Shift Del (DEL) | VAF 10/92 reads (11%) | called by mutect2, pindel, varscan2
- C5AR1 | c.8_10del p.S3del | In Frame Del (DEL) | VAF 6/64 reads (9%) | called by mutect2, pindel
- CCDC89 | c.175_177del p.E59del | In Frame Del (DEL) | VAF 8/31 reads (26%) | called by pindel, varscan2
- CFAP47 | c.5458del p.S1820Vfs*10 | Frame Shift Del (DEL) | VAF 31/211 reads (15%) | called by mutect2, pindel, varscan2
- CHD9 | c.2280del p.F760Lfs*16 | Frame Shift Del (DEL) | VAF 22/79 reads (28%) | called by mutect2, varscan2
- CKAP5 | c.4252_4254del p.E1418del | In Frame Del (DEL) | VAF 10/74 reads (14%) | called by pindel, varscan2
- COL4A3 | c.1131del p.G378Efs*22 | Frame Shift Del (DEL) | VAF 15/103 reads (15%) | called by mutect2, pindel, varscan2
- COL6A3 | c.7327del p.A2443Pfs*12 | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | called by mutect2, pindel, varscan2
- COPS7A | c.655del p.T219Pfs*21 | Frame Shift Del (DEL) | VAF 4/40 reads (10%) | called by pindel, varscan2
- CPEB2 | c.2941del p.C981Vfs*31 | Frame Shift Del (DEL) | VAF 20/161 reads (12%) | called by mutect2, pindel, varscan2
- CUL4B | c.857del p.L286* | Frame Shift Del (DEL) | VAF 31/258 reads (12%) | called by mutect2, pindel, varscan2
- DHX9 | c.3193del p.L1065Cfs*20 | Frame Shift Del (DEL) | VAF 28/166 reads (17%) | called by mutect2, pindel, varscan2
- DLST | c.1166del p.P389Lfs*18 | Frame Shift Del (DEL) | VAF 12/96 reads (13%) | called by mutect2, pindel, varscan2
- DNAH3 | c.4274del p.G1425Vfs*64 | Frame Shift Del (DEL) | VAF 23/174 reads (13%) | called by mutect2, pindel, varscan2
- DRP2 | c.1640_1641del p.E547Gfs*15 | Frame Shift Del (DEL) | VAF 11/91 reads (12%) | called by mutect2, pindel, varscan2
- DYNC1I2 | c.967del p.T323Lfs*13 | Frame Shift Del (DEL) | VAF 15/123 reads (12%) | called by mutect2, pindel, varscan2
- FAM177A1 | c.149dup p.K51Efs*12 (on ENST00000382406 / NM_001289022.2; = p.K74Efs*12 on NM_173607.5) | Frame Shift Ins (INS) | VAF 18/157 reads (11%) | called by mutect2, pindel, varscan2
- FCAR | c.194del p.N65Tfs*7 | Frame Shift Del (DEL) | VAF 22/79 reads (28%) | called by mutect2, pindel, varscan2
- FCGBP | c.9118A>G p.I3040V | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2
- FIGN | c.210dup p.Y71Ifs*35 | Frame Shift Ins (INS) | VAF 16/114 reads (14%) | called by mutect2, varscan2
- GJA8 | c.931del p.D311Tfs*46 | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | called by mutect2, varscan2
- ICE1 | c.978del p.F326Lfs*82 | Frame Shift Del (DEL) | VAF 16/91 reads (18%) | called by mutect2, pindel, varscan2
- IGHV3-43 | c.23T>A p.V8D | Missense Mutation (SNP) | VAF 50/299 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- IGSF8 | c.776del p.G259Vfs*49 | Frame Shift Del (DEL) | VAF 4/27 reads (15%) | called by mutect2, pindel
- KANSL1L | c.932del p.N311Mfs*63 | Frame Shift Del (DEL) | VAF 14/148 reads (9%) | called by pindel, varscan2
- KIF18A | c.1663_1664del p.M555Dfs*15 | Frame Shift Del (DEL) | VAF 40/295 reads (14%) | called by pindel, varscan2
- KLC1 | c.468del p.K156Nfs*65 | Frame Shift Del (DEL) | VAF 8/48 reads (17%) | called by mutect2, pindel
- MAP3K15 | c.521del p.N174Tfs*15 | Frame Shift Del (DEL) | VAF 6/43 reads (14%) | called by mutect2, pindel, varscan2
- MED12L | c.4249del p.L1417Sfs*14 | Frame Shift Del (DEL) | VAF 10/61 reads (16%) | called by mutect2, pindel, varscan2
- MED13L | c.3307dup p.I1103Nfs*22 | Frame Shift Ins (INS) | VAF 5/32 reads (16%) | called by mutect2, pindel, varscan2
- OR1L6 | c.13del p.Y5Tfs*6 | Frame Shift Del (DEL) | VAF 20/168 reads (12%) | called by mutect2, pindel, varscan2
- OR4C12 | c.909del p.V304* | Frame Shift Del (DEL) | VAF 16/129 reads (12%) | called by mutect2, pindel, varscan2
- OTOF | c.5291+1del p.X1764_splice (on ENST00000272371 / NM_194248.3; = p.X997_splice on NM_004802.4) | Splice Site (DEL) | VAF 4/18 reads (22%) | called by mutect2, pindel, varscan2
- PBRM1 | c.787_789del p.N263del | In Frame Del (DEL) | VAF 43/249 reads (17%) | called by mutect2, pindel, varscan2
- PI4KB | c.2036del p.L679Wfs*32 (on ENST00000368873 / NM_001369623.1; = p.L691Wfs*32 on NM_002651.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 11/107 reads (10%) | called by mutect2, varscan2
- PIGZ | c.1639del p.H547Ifs*2 | Frame Shift Del (DEL) | VAF 4/33 reads (12%) | called by mutect2, pindel, varscan2
- PPP4C | c.891del p.S298Pfs*28 | Frame Shift Del (DEL) | VAF 4/14 reads (29%) | called by mutect2, varscan2
- RAD51AP2 | c.946del p.T316Lfs*2 | Frame Shift Del (DEL) | VAF 44/268 reads (16%) | called by mutect2, pindel, varscan2
- SETX | c.5243del p.F1748Sfs*3 | Frame Shift Del (DEL) | VAF 16/134 reads (12%) | called by mutect2, pindel, varscan2
- SH3BGR | c.167del p.G56Efs*22 | Frame Shift Del (DEL) | VAF 18/129 reads (14%) | called by mutect2, pindel, varscan2
- SHLD2 | c.2467del p.Y823Ifs*5 | Frame Shift Del (DEL) | VAF 14/129 reads (11%) | called by mutect2, varscan2
- SIPA1L1 | c.2180dup p.N727Kfs*21 | Frame Shift Ins (INS) | VAF 14/138 reads (10%) | called by mutect2, varscan2
- SLC16A6 | c.995del p.L332Yfs*38 | Frame Shift Del (DEL) | VAF 5/38 reads (13%) | called by mutect2, pindel, varscan2
- TMEM144 | c.865_866del p.L289Efs*26 | Frame Shift Del (DEL) | VAF 47/307 reads (15%) | called by pindel, varscan2
- TRIM45 | c.1127_1129del p.P376del | In Frame Del (DEL) | VAF 12/77 reads (16%) | called by mutect2, pindel, varscan2
- TRIM5 | c.812del p.N271Ifs*11 | Frame Shift Del (DEL) | VAF 55/405 reads (14%) | called by mutect2, pindel, varscan2
- TRIM75P | c.504dup p.P169Tfs*18 | Frame Shift Ins (INS) | VAF 12/90 reads (13%) | called by mutect2, pindel, varscan2
- UBC | c.2003_2005del p.N668del | In Frame Del (DEL) | VAF 21/81 reads (26%) | called by pindel, varscan2
- USP9X | c.5319del p.K1773Nfs*9 | Frame Shift Del (DEL) | VAF 48/152 reads (32%) | called by mutect2, pindel, varscan2
- VCAM1 | c.1844_1846del p.E615del | In Frame Del (DEL) | VAF 12/90 reads (13%) | called by pindel, varscan2
- WDFY3 | c.3179del p.L1060Cfs*41 | Frame Shift Del (DEL) | VAF 11/121 reads (9%) | called by mutect2, pindel
- ZNF416 | c.693del p.H232Tfs*54 | Frame Shift Del (DEL) | VAF 15/120 reads (13%) | called by mutect2, pindel, varscan2
- AARS1 | c.576C>T p.Y192= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as rs930696946, COSV55749717; called by muse, mutect2, varscan2
- ABHD2 | c.1206C>T p.N402= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as rs746027991, COSV61776419; called by muse, mutect2, varscan2
- ADGRA2 | c.1311C>A p.A437= | Silent (SNP) | VAF 3/21 reads (14%) | catalogued as COSV59447491; called by muse, mutect2
- AGO4 | c.168G>A p.R56= | Silent (SNP) | VAF 5/69 reads (7%) | catalogued as COSV64618796; called by muse, mutect2
- AMTN | c.540C>T p.D180= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs747462345, COSV59490283; called by muse, mutect2, varscan2
- ANGPT2 | c.1230C>A p.A410= | Silent (SNP) | VAF 17/118 reads (14%) | catalogued as COSV100291311, COSV57340542; called by muse, mutect2, varscan2
- ANKFY1 | c.2662C>T p.L888= (on ENST00000341657 / NM_001330063.2; = p.L889= on NM_016376.5) | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as COSV58923290; called by muse, mutect2, varscan2
- ANKRD11 | c.2355C>T p.D785= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as COSV56372525; called by muse, mutect2, varscan2
- ANKRD28 | c.1482C>T p.N494= | Silent (SNP) | VAF 15/171 reads (9%) | catalogued as rs369619563; called by muse, mutect2
- ATF5 | c.823C>A p.R275= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV61313787; called by muse, mutect2
- ATP11B | c.3006C>T p.G1002= | Silent (SNP) | VAF 22/181 reads (12%) | catalogued as COSV60033600; called by muse, mutect2, varscan2
- BAIAP2L1 | c.705G>A p.V235= | Silent (SNP) | VAF 4/66 reads (6%) | catalogued as COSV50061212; called by muse, mutect2
- C1orf198 | c.828C>T p.H276= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as rs750314997, COSV64175041; called by muse, mutect2, varscan2
- CBX3 | c.36A>G p.G12= | Silent (SNP) | VAF 22/115 reads (19%) | catalogued as rs751559785, COSV61761904; called by muse, varscan2
- CCAR1 | c.369G>A p.Q123= | Silent (SNP) | VAF 8/216 reads (4%) | catalogued as COSV56274795; called by muse, mutect2
- CCDC68 | c.387C>T p.N129= | Silent (SNP) | VAF 15/115 reads (13%) | catalogued as rs747918940, COSV61604941; called by muse, mutect2, varscan2
- CCM2 | c.684T>C p.F228= | Silent (SNP) | VAF 5/51 reads (10%) | catalogued as rs1011954212, COSV51851521; called by muse, mutect2, varscan2
- CHI3L1 | c.372G>A p.P124= | Silent (SNP) | VAF 11/103 reads (11%) | catalogued as rs756775296, COSV55138175; called by muse, mutect2, varscan2
- CHIA | c.621C>T p.I207= (on ENST00000343320; = p.I99= on NM_021797.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 36/114 reads (32%) | catalogued as COSV100588831, COSV58478460; called by muse, mutect2, varscan2
- CLEC4F | c.363C>T p.I121= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs540670274, COSV55481701; called by muse, mutect2, varscan2
- COL24A1 | c.405A>G p.V135= | Silent (SNP) | VAF 11/94 reads (12%) | catalogued as rs1186724727, COSV65306789; called by muse, mutect2, varscan2
- CPE | c.444T>C p.S148= | Silent (SNP) | VAF 29/143 reads (20%) | catalogued as COSV68582751; called by muse, mutect2, varscan2
- CTNNBL1 | c.1135T>C p.L379= | Silent (SNP) | VAF 12/85 reads (14%) | catalogued as COSV63747482; called by muse, mutect2, varscan2
- CTNND2 | c.2766C>T p.D922= | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as rs746806956, COSV58930045; called by muse, mutect2, varscan2
- DAAM1 | c.2775G>T p.V925= | Silent (SNP) | VAF 14/148 reads (9%) | catalogued as rs1279124928, COSV62839951; called by muse, mutect2
- DACT1 | c.282G>A p.A94= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as rs1234488059, COSV60023611; called by muse, mutect2, varscan2
- DLC1 | c.4359C>T p.R1453= (on ENST00000276297 / NM_001348081.2; = p.R1016= on NM_006094.5) | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as rs141467403; called by muse, mutect2, varscan2
- DLGAP5 | c.2499T>C p.G833= | Silent (SNP) | VAF 10/157 reads (6%) | catalogued as COSV54306486; called by muse, mutect2
- DNMT1 | c.897C>T p.P299= | Silent (SNP) | VAF 40/162 reads (25%) | catalogued as rs373861581; called by muse, mutect2, varscan2
- DNTT | c.150G>A p.A50= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as rs372756048; called by muse, mutect2, varscan2
- DTL | c.1275T>C p.S425= | Silent (SNP) | VAF 24/151 reads (16%) | catalogued as COSV65343282; called by muse, mutect2, varscan2
- EDRF1 | c.2157T>G p.A719= (on ENST00000356792 / NM_001202438.2; = p.A685= on NM_015608.2) | Silent (SNP) | VAF 30/113 reads (27%) | catalogued as COSV61766315; called by muse, mutect2, varscan2
- ENY2 | c.183C>T p.H61= | Silent (SNP) | VAF 38/549 reads (7%) | catalogued as rs754811292, COSV60566070; called by muse, mutect2
- EPB41L2 | c.2490C>T p.H830= | Silent (SNP) | VAF 26/288 reads (9%) | catalogued as rs745805908, COSV61359256; called by muse, mutect2
- ERLEC1 | c.1374T>C p.I458= | Silent (SNP) | VAF 36/150 reads (24%) | catalogued as rs370895718; called by muse, varscan2
- FDPS | c.537G>T p.R179= | Silent (SNP) | VAF 16/158 reads (10%) | catalogued as COSV63115518; called by muse, varscan2
- FMN1 | c.3750G>A p.P1250= (on ENST00000616417 / NM_001277313.2; = p.P1027= on NM_001103184.4) | Silent (SNP) | VAF 24/334 reads (7%) | catalogued as rs752742684, COSV57934189; called by muse, mutect2
- HADH | c.249A>T p.A83= | Silent (SNP) | VAF 27/118 reads (23%) | catalogued as COSV58850316; called by muse, mutect2, varscan2
- HCLS1 | c.483C>T p.Y161= | Silent (SNP) | VAF 7/113 reads (6%) | catalogued as rs919352133, COSV58860519; called by muse, mutect2
- HMCN1 | c.16743C>A p.A5581= | Silent (SNP) | VAF 5/80 reads (6%) | catalogued as COSV54943640; called by muse, mutect2
- INTS3 | c.480C>T p.A160= | Silent (SNP) | VAF 93/761 reads (12%) | catalogued as COSV59681747; called by muse, mutect2, varscan2
- IQGAP2 | c.621G>A p.L207= | Silent (SNP) | VAF 36/136 reads (26%) | catalogued as rs778648669, COSV57170939, COSV57183086; called by muse, mutect2, varscan2
- KCND3 | c.1815C>T p.C605= | Silent (SNP) | VAF 6/116 reads (5%) | catalogued as COSV56190166; called by muse, mutect2
- KIAA0319L | c.2400C>T p.V800= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV57851007; called by muse, mutect2, varscan2
- KIRREL1 | c.2214C>T p.Y738= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as rs754500286, COSV63291577; called by mutect2, varscan2
- KPRP | c.465C>A p.P155= | Silent (SNP) | VAF 12/163 reads (7%) | catalogued as COSV64223048; called by muse, mutect2
- LAMB2 | c.264C>T p.C88= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV59738198; called by muse, varscan2
- LCMT1 | c.759G>A p.A253= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as rs769309569, COSV66727364; called by muse, mutect2
- LDOC1 | c.207G>A p.V69= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV65159720; called by muse, mutect2, varscan2
- MAG | c.213G>A p.P71= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as rs199750254, COSV62699502; called by muse, mutect2, varscan2
- MAGI1 | c.4083C>T p.R1361= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV58345691; called by mutect2, varscan2
- MARK1 | c.2115T>C p.S705= | Silent (SNP) | VAF 4/78 reads (5%) | catalogued as COSV65071638; called by muse, mutect2
- MAST1 | c.1764C>T p.F588= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as rs1018835734, COSV52255526; called by muse, mutect2, varscan2
- MED12 | c.1650G>A p.K550= | Silent (SNP) | VAF 44/291 reads (15%) | catalogued as COSV61354766, COSV61356627; called by muse, mutect2, varscan2
- MED14 | c.4342C>T p.L1448= | Silent (SNP) | VAF 21/100 reads (21%) | catalogued as COSV59948216; called by muse, mutect2, varscan2
- MGLL | c.492G>A p.A164= (on ENST00000398104 / NM_001003794.2; = p.A174= on NM_007283.6) | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs370914770; called by mutect2, varscan2
- MSANTD4 | c.654A>G p.R218= | Silent (SNP) | VAF 9/165 reads (5%) | catalogued as COSV57286954; called by muse, mutect2
- MUC16 | c.555T>C p.I185= | Silent (SNP) | VAF 23/293 reads (8%) | catalogued as COSV67495616; called by muse, mutect2
- MUSK | c.951C>T p.C317= | Silent (SNP) | VAF 23/84 reads (27%) | catalogued as rs1311522447, COSV51897294; called by muse, mutect2, varscan2
- MVK | c.417C>T p.P139= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs754441368, COSV57330737, COSV57331520; called by mutect2, varscan2
- MYBL2 | c.609G>A p.L203= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as COSV53833920; called by muse, mutect2, varscan2
- MYL6B | c.546G>A p.V182= | Silent (SNP) | VAF 18/103 reads (17%) | catalogued as COSV52879761; called by muse, mutect2, varscan2
- MYL9 | c.234G>A p.P78= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs751511018, COSV54072306, COSV54073025; called by muse, mutect2, varscan2
- NDRG2 | c.912C>T p.T304= (on ENST00000298687 / NM_001354570.1; = p.T290= on NM_016250.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 22/85 reads (26%) | catalogued as rs140065557; called by muse, mutect2, varscan2
- NEUROD1 | c.141C>T p.N47= | Silent (SNP) | VAF 14/214 reads (7%) | catalogued as rs1046216784, COSV54549546; called by muse, mutect2
- NIN | c.1557C>T p.L519= | Silent (SNP) | VAF 13/78 reads (17%) | catalogued as rs752316600, COSV55407113; called by muse, mutect2, varscan2
- NLE1 | c.885C>A p.L295= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV62605238; called by mutect2, varscan2
- NR2E1 | c.873C>T p.I291= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs368041869, COSV100934610; called by muse, mutect2, varscan2
- OAZ3 | c.501C>T p.Y167= | Silent (SNP) | VAF 23/216 reads (11%) | catalogued as rs765364327, COSV100162339, COSV58619734; called by muse, mutect2, varscan2
- OR13C2 | c.288C>T p.G96= | Silent (SNP) | VAF 14/144 reads (10%) | catalogued as COSV73377628, COSV73377799; called by muse, mutect2, varscan2
- OR2AT4 | c.762C>T p.G254= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV59407771; called by muse, mutect2, varscan2
- OR5M8 | c.723C>A p.G241= | Silent (SNP) | VAF 22/58 reads (38%) | catalogued as COSV59118319; called by muse, mutect2, varscan2
- OR5P3 | c.768C>A p.T256= | Silent (SNP) | VAF 12/94 reads (13%) | catalogued as COSV60429424; called by muse, mutect2, varscan2
- OR6C68 | c.564A>G p.S188= | Silent (SNP) | VAF 37/174 reads (21%) | catalogued as rs1051779538, COSV65563990; called by muse, mutect2, varscan2
- PARP8 | c.258T>C p.F86= | Silent (SNP) | VAF 53/174 reads (30%) | catalogued as rs771599487, COSV55858094, COSV55867223; called by muse, mutect2, varscan2
- PCCA | c.750T>C p.A250= | Silent (SNP) | VAF 9/178 reads (5%) | catalogued as COSV66199169; called by muse, mutect2
- PDK3 | c.765G>A p.A255= | Silent (SNP) | VAF 51/264 reads (19%) | catalogued as rs1277836754, COSV64794521; called by muse, mutect2, varscan2
- PDS5B | c.594G>A p.T198= | Silent (SNP) | VAF 36/280 reads (13%) | catalogued as rs1473202090, COSV59734840; called by muse, mutect2, varscan2
- PGAM1 | c.267G>A p.E89= | Silent (SNP) | VAF 7/66 reads (11%) | catalogued as COSV58356341; called by muse, mutect2, varscan2
- PHF12 | c.2058C>T p.N686= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as COSV52022361; called by muse, mutect2, varscan2
- PIBF1 | c.834A>T p.V278= | Silent (SNP) | VAF 24/172 reads (14%) | catalogued as COSV58328577; called by muse, mutect2, varscan2
- POLQ | c.7107T>C p.I2369= | Silent (SNP) | VAF 15/84 reads (18%) | catalogued as COSV51761895; called by muse, mutect2, varscan2
- POLR1A | c.2658C>T p.H886= | Silent (SNP) | VAF 3/35 reads (9%) | catalogued as COSV55699969; called by muse, mutect2
- PRKDC | c.2256G>A p.L752= | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as COSV58064671; called by muse, mutect2
- PRMT2 | c.1287C>T p.F429= | Silent (SNP) | VAF 6/140 reads (4%) | catalogued as COSV52458023; called by muse, mutect2
- PWP1 | c.1203C>T p.L401= | Silent (SNP) | VAF 32/93 reads (34%) | catalogued as rs543920809, COSV69833082; called by muse, mutect2, varscan2
- RAD51AP1 | c.186A>G p.V62= | Silent (SNP) | VAF 25/79 reads (32%) | catalogued as COSV57412461; called by muse, mutect2, varscan2
- RALGAPB | c.1422T>C p.I474= | Silent (SNP) | VAF 56/178 reads (31%) | catalogued as rs1275069150, COSV53444592; called by muse, mutect2, varscan2
- RC3H2 | c.3303T>C p.N1101= | Silent (SNP) | VAF 33/105 reads (31%) | catalogued as COSV61802611; called by muse, mutect2, varscan2
- RGS16 | c.519G>A p.K173= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as rs757534797, COSV62376011; called by muse, mutect2, varscan2
- RORC | c.666C>T p.S222= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV59095911; called by mutect2, varscan2
- SAMD9L | c.1476G>A p.Q492= | Silent (SNP) | VAF 18/115 reads (16%) | catalogued as COSV59085488; called by muse, mutect2, varscan2
- SASH1 | c.555C>T p.S185= | Silent (SNP) | VAF 45/259 reads (17%) | catalogued as rs764763178, COSV66559672; called by muse, mutect2, varscan2
- SEMA4A | c.1011G>A p.A337= | Silent (SNP) | VAF 23/165 reads (14%) | catalogued as rs374618030; called by muse, mutect2, varscan2
- SF3B1 | c.3049C>T p.L1017= | Silent (SNP) | VAF 26/176 reads (15%) | catalogued as COSV59228258; called by muse, mutect2, varscan2
- SGIP1 | c.540A>G p.T180= | Silent (SNP) | VAF 23/236 reads (10%) | catalogued as COSV52779408; called by muse, mutect2, varscan2
- SLC12A5 | c.1470C>T p.G490= (on ENST00000454036 / NM_001134771.2; = p.G467= on NM_020708.5) | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as rs545847050, COSV54802349; called by muse, mutect2, varscan2
- SLC26A3 | c.900A>T p.A300= | Silent (SNP) | VAF 8/81 reads (10%) | catalogued as COSV60642860; called by muse, mutect2, varscan2
- SLC26A5 | c.126T>C p.I42= | Silent (SNP) | VAF 29/145 reads (20%) | catalogued as COSV59706097; called by muse, mutect2, varscan2
- SLC5A1 | c.1602C>T p.F534= | Silent (SNP) | VAF 82/486 reads (17%) | catalogued as rs776740141, COSV56688519; called by muse, mutect2, varscan2
- SLTM | c.2841T>C p.Y947= | Silent (SNP) | VAF 11/117 reads (9%) | catalogued as COSV65850424; called by muse, mutect2
- SMARCA2 | c.1059C>T p.R353= | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as COSV61812950; called by muse, mutect2, varscan2
- SYBU | c.39G>A p.V13= (on ENST00000276646 / NM_001099754.2; = p.V12= on NM_017786.6) | Silent (SNP) | VAF 4/68 reads (6%) | catalogued as COSV52623228; called by muse, mutect2
- SYT10 | c.375A>G p.K125= | Silent (SNP) | VAF 22/173 reads (13%) | catalogued as COSV57345847; called by muse, mutect2, varscan2
- TAF7 | c.918C>T p.I306= | Silent (SNP) | VAF 37/204 reads (18%) | catalogued as rs950057614, COSV57665491; called by muse, mutect2, varscan2
- TCEAL3 | c.72T>C p.P24= | Silent (SNP) | VAF 111/864 reads (13%) | catalogued as COSV54581521; called by muse, mutect2, varscan2
- TEX10 | c.579G>A p.Q193= | Silent (SNP) | VAF 9/71 reads (13%) | catalogued as COSV66518713; called by muse, mutect2, varscan2
- TGFB2 | c.1140C>T p.C380= | Silent (SNP) | VAF 24/233 reads (10%) | catalogued as rs201129153; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- TLR8 | c.2625A>G p.T875= (on ENST00000218032 / NM_138636.5; = p.T893= on NM_016610.4) | Silent (SNP) | VAF 6/150 reads (4%) | catalogued as COSV54320875; called by muse, mutect2
- TMEM169 | c.546C>T p.Y182= | Silent (SNP) | VAF 59/339 reads (17%) | catalogued as rs773725400, COSV55264328; called by muse, mutect2, varscan2
- TSPOAP1 | c.213C>T p.P71= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as rs764136460, COSV52118313; called by muse, mutect2, varscan2
- TTC26 | c.1317T>C p.I439= | Silent (SNP) | VAF 10/102 reads (10%) | catalogued as COSV58274669; called by muse, mutect2, varscan2
- TXNDC5 | c.1207C>A p.R403= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as COSV51664800, COSV51672705; called by muse, mutect2, varscan2
- UNC45B | c.2088C>T p.H696= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as rs778530797, COSV52092618, COSV52099357; called by muse, mutect2, varscan2
- USH2A | c.1449G>A p.T483= | Silent (SNP) | VAF 18/214 reads (8%) | catalogued as rs755603663, COSV56389487; called by muse, mutect2
- USP31 | c.3303G>A p.P1101= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs1450483712, COSV54849934; called by muse, mutect2
- WNK4 | c.3033G>A p.P1011= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as rs780181511, COSV55910816; called by muse, mutect2
- XPO4 | c.3241T>C p.L1081= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV55013647; called by muse, mutect2, varscan2
- YTHDF3 | c.213T>C p.L71= | Silent (SNP) | VAF 9/63 reads (14%) | catalogued as COSV72773924; called by muse, mutect2, varscan2
- ZBTB40 | c.264C>T p.H88= | Silent (SNP) | VAF 25/69 reads (36%) | catalogued as COSV65146469; called by muse, mutect2, varscan2
- ZIC4 | c.588C>T p.R196= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV67174211; called by muse, mutect2
- ZNF19 | c.822G>A p.E274= | Silent (SNP) | VAF 16/162 reads (10%) | catalogued as COSV55509040; called by muse, mutect2
- ZNF23 | c.1353T>C p.N451= | Silent (SNP) | VAF 19/158 reads (12%) | catalogued as COSV61841781; called by muse, mutect2, varscan2
- ZNF700 | c.2082T>C p.H694= | Silent (SNP) | VAF 7/73 reads (10%) | catalogued as COSV54315463; called by muse, mutect2
- FMO3 | c.133-2019C>T | Intron (SNP) | VAF 6/82 reads (7%) | catalogued as COSV63008667; called by muse, mutect2
- MYO19 | c.894+18G>A | Intron (SNP) | VAF 5/40 reads (13%) | catalogued as rs746087767; called by muse, mutect2, varscan2
- PARGP1 | n.1826C>A | RNA (SNP) | VAF 28/357 reads (8%) | called by muse, mutect2
- RBM44 | c.-98-2574T>C | Intron (SNP) | VAF 8/31 reads (26%) | catalogued as rs1488464732, COSV57633419; called by muse, mutect2
- RRP7A | c.*3842G>A | 3'UTR (SNP) | VAF 6/42 reads (14%) | catalogued as rs746164535; called by muse, mutect2, varscan2
- TTN | c.10361-3964dup | Intron (INS) | VAF 14/90 reads (16%) | catalogued as rs1560961746; called by mutect2, varscan2
